Somatic mutation profile of tumor specimen 0DOLV8 from CCDI case PBBRLT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucoepidermoid carcinoma; Tissue or organ of origin: Hard palate; Age at diagnosis: 7.0 years (2,556 days).
Specimen 0DOLV8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cac7a24c-6ee1-44b8-bf44-757264e7c36d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOLUP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cd5dcac-fe13-49a5-ae66-dcb6a08b5f52

The open-access MAF lists 3 somatic variants for this specimen: 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K15 | c.2550G>A p.P850= | Silent (SNP) | VAF 40/1014 reads (4%) | catalogued as rs1478185273, COSV100134691; called by muse, mutect2
- LRRC63 | c.*79T>G | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 20/146 reads (14%) | called by muse, varscan2
